Somatic mutation profile of tumor specimen C3N-00858-01 (aliquot CPT0078320010) from CPTAC case C3N-00858, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.8 years (24,019 days).
Specimen C3N-00858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d674ee59-6fcd-49c2-bfa0-35b7d11dd579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00858-31 (Blood Derived Normal), aliquot CPT0078420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5181dfc-8666-4f63-98e0-b79f8ad94772

The open-access MAF lists 105 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 23, Nonsense Mutation 7, Frame Shift Ins 4, Splice Site 4, In Frame Del 3, Intron 3, Frame Shift Del 3, RNA 2, 3'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1609T>A p.Y537N | Missense Mutation (SNP) | VAF 85/502 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52784978, COSV52804811, COSV99237981; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 66/180 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.860C>G p.S287* | Nonsense Mutation (SNP) | VAF 82/238 reads (34%) | catalogued as rs863224909, COSV104426445, COSV64291895; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.900del p.I300Mfs*7 | Frame Shift Del (DEL) | VAF 82/293 reads (28%) | catalogued as rs797045904, CD115955, COSV64288931, COSV64289107; ClinVar: pathogenic; called by pindel, varscan2
- TNR | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | catalogued as rs1287757170, COSV99687070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53932818; called by muse, mutect2
- ATG2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs145947897, COSV65966328; called by muse, mutect2
- AXL | c.1423C>T p.R475* (on ENST00000301178 / NM_021913.5; = p.R466* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 70/203 reads (34%) | catalogued as rs1307122843; called by muse, mutect2, varscan2
- BRINP1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745883942, COSV56315483; called by muse, mutect2, varscan2
- CARD10 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs769186770; called by muse, mutect2, varscan2
- CD276 | c.1120C>T p.R374W (on ENST00000318443 / NM_001024736.2; = p.R156W on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754785892, COSV100573437; called by muse, mutect2, varscan2
- CDH7 | c.1070C>A p.P357Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- DCANP1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as rs752321523, COSV101538227; called by muse, mutect2, varscan2
- DNAH9 | c.7150G>A p.G2384R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs267604735; called by muse, mutect2, varscan2
- DNASE1L2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs777878114; called by muse, mutect2, varscan2
- ERBB3 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 146/555 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs370634710; called by muse, mutect2, varscan2
- ETF1 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV62127698; called by muse, mutect2
- FGG | c.1314C>A p.H438Q | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100272024; called by muse, mutect2, varscan2
- GABRB3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777882335, COSV54663217; called by muse, mutect2, varscan2
- GAGE10 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.094); catalogued as rs781953021; called by muse, mutect2
- GPR45 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs746939000, COSV51523283, COSV51525996; called by muse, mutect2, varscan2
- GYS1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs1314644112; called by muse, mutect2
- HTR1D | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs201355267; called by muse, mutect2, varscan2
- KDR | c.2942A>T p.K981M | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV55775023; called by muse, mutect2, varscan2
- MPP7 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs578191058; called by muse, mutect2, varscan2
- MYNN | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs147441397; called by muse, mutect2, varscan2
- PAPPA2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.116); catalogued as rs371276745; called by muse, mutect2, varscan2
- PKHD1 | c.8671C>T p.R2891C | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs148990124; ClinVar: uncertain significance; called by muse, varscan2
- PTPN13 | c.6499G>A p.D2167N (on ENST00000411767 / NM_080683.3; = p.D2148N on NM_006264.3) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1315321262; called by muse, mutect2, varscan2
- SBNO2 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs781471532; called by muse, mutect2, varscan2
- SCRIB | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 121/179 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs782244284; called by muse, mutect2, varscan2
- SEC14L5 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs202152916; called by muse, mutect2, varscan2
- SPATC1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs374196194, COSV101084953; called by muse, mutect2, varscan2
- SPTB | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1181994000, COSV67633581; called by muse, mutect2, varscan2
- SPTBN2 | c.3011C>T p.T1004M | Missense Mutation (SNP) | VAF 114/732 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs746835288; called by muse, mutect2, varscan2
- SYNPO2L | c.2306C>T p.A769V (on ENST00000394810 / NM_001114133.3; = p.A545V on NM_024875.5) | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs749142151; called by muse, mutect2, varscan2
- THBS3 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 114/318 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs200951846, COSV57428524; called by muse, mutect2, varscan2
- WDR13 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1457822867, COSV54331510; called by muse, mutect2, varscan2
- ZNF208 | c.2369C>A p.A790E | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV68110442; called by muse, mutect2, varscan2
- ZNF397 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746286942, COSV54350505; called by muse, mutect2, varscan2
- ZNF529 | c.375C>G p.S125R | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV61902132; called by muse, mutect2, varscan2
- ZNF536 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62825910, COSV62830461; called by muse, mutect2, varscan2
- ZNF835 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.958); catalogued as rs1442779848, COSV73379250; called by muse, mutect2, varscan2
- ADAM10 | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 73/503 reads (15%) | called by muse, mutect2, varscan2
- ANKRD30B | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.065); called by muse, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, varscan2
- AURKB | c.10_12del p.K4del | In Frame Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- BPTF | c.5173T>A p.S1725T | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); called by muse, varscan2
- CCNB3 | c.205-4_205delinsTTTTT p.X69_splice | Splice Site (ONP) | VAF 4/49 reads (8%) | called by mutect2*, pindel
- CLCN3 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL1A2 | c.2563_2565+14del p.X855_splice | Splice Site (DEL) | VAF 59/467 reads (13%) | called by pindel, varscan2
- COPG1 | c.1068dup p.I357Hfs*18 | Frame Shift Ins (INS) | VAF 20/185 reads (11%) | called by mutect2, pindel, varscan2
- CRHBP | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ESYT2 | c.1153-42_1153-2del p.X385_splice (on ENST00000613624; = p.X309_splice on NM_020728.3) | Splice Site (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel
- EXOC4 | c.1900G>C p.V634L | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- GFOD2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GIGYF2 | c.2828_2829insA p.L944Afs*5 | Frame Shift Ins (INS) | VAF 90/422 reads (21%) | called by pindel, varscan2
- HSD17B6 | c.917del p.L306* | Frame Shift Del (DEL) | VAF 63/268 reads (24%) | called by mutect2, pindel, varscan2
- LCT | c.3015T>G p.N1005K | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- MAGEL2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.19); called by muse, mutect2, varscan2
- PIK3R1 | c.1728_1736del p.R577_Q579del (on ENST00000521381 / NM_181523.3; = p.R307_Q309del on NM_181504.4) | In Frame Del (DEL) | VAF 47/153 reads (31%) | called by mutect2, pindel, varscan2
- POSTN | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RBM10 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 136/398 reads (34%) | called by muse, mutect2, varscan2
- RBM39 | c.1222_1225+1del p.X408_splice (on ENST00000253363 / NM_001323424.2; = p.X402_splice on NM_004902.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 50/133 reads (38%) | called by mutect2, pindel, varscan2
- RRAGA | c.508T>A p.Y170N | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.1585dup p.M529Nfs*3 | Frame Shift Ins (INS) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- SEMA4G | c.2473A>T p.K825* (on ENST00000370250; = p.K830* on NM_017893.3) | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- SI | c.1718C>A p.A573D | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A12 | c.1586-8C>A | Splice Region (SNP) | VAF 93/257 reads (36%) | called by muse, mutect2, varscan2
- SOS2 | c.3704A>G p.Q1235R | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TAF1 | c.2329A>G p.K777E (on ENST00000373790 / NM_138923.4; = p.K798E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPOAP1 | c.5161C>A p.P1721T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- UBR4 | c.14224_14229del p.T4742_D4743del | In Frame Del (DEL) | VAF 91/226 reads (40%) | called by mutect2, pindel, varscan2
- ZNF264 | c.1422del p.F474Lfs*96 | Frame Shift Del (DEL) | VAF 22/174 reads (13%) | called by mutect2, varscan2
- ATP2B3 | c.1182G>A p.T394= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs782157015, COSV54844558, COSV54862482; called by muse, mutect2, varscan2
- B4GALNT4 | c.1644G>A p.P548= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CEP152 | c.4842C>T p.S1614= (on ENST00000380950 / NM_001194998.2; = p.S1558= on NM_014985.4) | Silent (SNP) | VAF 144/362 reads (40%) | catalogued as rs765678153, COSV100358550; called by muse, mutect2, varscan2
- CNNM1 | c.1149G>A p.A383= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as COSV100763809, COSV63201890, COSV63204000; called by muse, mutect2, varscan2
- ECEL1 | c.615C>T p.I205= | Silent (SNP) | VAF 28/560 reads (5%) | called by muse, mutect2
- FAM151A | c.288C>T p.D96= | Silent (SNP) | VAF 28/188 reads (15%) | catalogued as rs765149719, COSV56362879; called by muse, mutect2
- FGF13 | c.687C>T p.V229= | Silent (SNP) | VAF 86/196 reads (44%) | called by muse, mutect2, varscan2
- GALR1 | c.993T>C p.T331= | Silent (SNP) | VAF 42/181 reads (23%) | called by mutect2, varscan2
- GFY | c.762C>T p.T254= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- GRK2 | c.1407G>A p.P469= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as rs755199751; called by muse, mutect2, varscan2
- GYPA | c.402C>T p.D134= | Silent (SNP) | VAF 59/346 reads (17%) | catalogued as rs757151303; called by muse, mutect2, varscan2
- HS3ST2 | c.75G>A p.T25= | Silent (SNP) | VAF 99/237 reads (42%) | called by muse, mutect2, varscan2
- MAP10 | c.645C>T p.D215= | Silent (SNP) | VAF 30/186 reads (16%) | catalogued as COSV69364856; called by muse, mutect2, varscan2
- MYH6 | c.1749C>T p.Y583= | Silent (SNP) | VAF 110/539 reads (20%) | catalogued as rs187508349; ClinVar: likely benign; called by muse, mutect2, varscan2
- NET1 | c.882C>G p.L294= (on ENST00000355029 / NM_001047160.3; = p.L240= on NM_005863.5) | Silent (SNP) | VAF 34/300 reads (11%) | catalogued as COSV61791859; called by muse, mutect2, varscan2
- NOP14 | c.264C>T p.F88= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs375247657; called by muse, mutect2, varscan2
- OR2V2 | c.522G>A p.K174= | Silent (SNP) | VAF 30/297 reads (10%) | catalogued as rs887376019; called by muse, mutect2, varscan2
- PCDHA9 | c.1557G>A p.A519= | Silent (SNP) | VAF 335/929 reads (36%) | catalogued as COSV65324640; called by muse, mutect2, varscan2
- POMC | c.396G>A p.P132= | Silent (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- RHO | c.180C>T p.Y60= | Silent (SNP) | VAF 38/331 reads (11%) | catalogued as rs527236101, CM1312821; called by muse, mutect2, varscan2
- RUSC2 | c.2439C>T p.S813= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs753397139; called by muse, mutect2, varscan2
- SI | c.4077T>C p.H1359= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs886058142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC18 | c.1911C>A p.L637= | Silent (SNP) | VAF 46/229 reads (20%) | catalogued as COSV101259497; called by muse, mutect2, varscan2
- AFF3 | chr2:100105689 G>C | 5'Flank (SNP) | VAF 90/252 reads (36%) | catalogued as rs1308782381; called by muse, mutect2, varscan2
- ASIC2 | c.556-179757G>A | Intron (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- DCD | c.98-369C>A | Intron (SNP) | VAF 157/304 reads (52%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.378C>T | RNA (SNP) | VAF 26/242 reads (11%) | catalogued as rs1255405340; called by muse, mutect2, varscan2
- PLPP5 | c.74+12C>A | Intron (SNP) | VAF 160/244 reads (66%) | called by muse, mutect2, varscan2
- RTL8B | c.*423G>A | 3'UTR (SNP) | VAF 24/416 reads (6%) | catalogued as rs1260857401; called by muse, mutect2
- SLURP2 | c.*28G>A | 3'UTR (SNP) | VAF 10/70 reads (14%) | catalogued as rs775302834; called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1248C>A | RNA (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
